Somatic mutation profile of tumor specimen TCGA-GC-A3I6-01A (aliquot TCGA-GC-A3I6-01A-11D-A20D-08) from TCGA case TCGA-GC-A3I6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 45.2 years (16,504 days).
Specimen TCGA-GC-A3I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 076e040a-8503-47fa-b656-03d0271fa22c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3I6-10A (Blood Derived Normal), aliquot TCGA-GC-A3I6-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d41bcada-845e-4194-aabf-cc7a09467693

The open-access MAF lists 214 somatic variants for this specimen: 153 protein-altering or splice-affecting, 56 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 56, Nonsense Mutation 13, Intron 3, Frame Shift Del 2, Splice Site 2, Splice Region 2, Frame Shift Ins 2, 5'Flank 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 75/159 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as rs1064793732, CM126690, COSV55881636, COSV55977337; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1BG | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV54050913; called by muse, mutect2, varscan2
- ABCC1 | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60685792; called by muse, mutect2, varscan2
- ACE | c.2387G>C p.R796T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV52006742; called by muse, mutect2, varscan2
- AGPAT2 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100451872; called by muse, mutect2, varscan2
- AGPAT3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52370361, COSV99377071; called by muse, mutect2, varscan2
- AHNAK | c.3943G>A p.E1315K | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.149); catalogued as COSV57213289, COSV57234459; called by muse, mutect2
- AHNAK2 | c.12331G>A p.D4111N | Missense Mutation (SNP) | VAF 22/421 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.86); catalogued as rs768643650, COSV60915339; called by muse, mutect2
- ANKRD11 | c.1132A>G p.N378D | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV56360878; called by muse, mutect2, varscan2
- ANO4 | c.1312+1G>A p.X438_splice (on ENST00000392977 / NM_001286615.2; = p.X403_splice on NM_178826.4) | Splice Site (SNP) | VAF 17/64 reads (27%) | catalogued as COSV54595866; called by muse, mutect2, varscan2
- ARID4B | c.3862G>A p.A1288T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51603188; called by muse, mutect2, varscan2
- ARIH2 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62704776; called by muse, mutect2, varscan2
- ASB4 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.082); catalogued as COSV57945266; called by muse, mutect2, varscan2
- ATAD2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV54880830; called by muse, mutect2, varscan2
- ATAD5 | c.1212G>A p.M404I | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58974622, COSV58977196; called by muse, mutect2, varscan2
- ATAD5 | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV58974632; called by muse, mutect2, varscan2
- ATAD5 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.212); catalogued as COSV58974643; called by muse, mutect2, varscan2
- ATP13A1 | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1249353960; called by muse, mutect2
- ATP7B | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54438406; called by muse, mutect2, varscan2
- BECN1 | c.1092G>C p.K364N | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59311956; called by muse, varscan2
- C1orf116 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV63944066; called by muse, mutect2, varscan2
- CAPN13 | c.952C>G p.Q318E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.074); catalogued as COSV54430654; called by muse, mutect2, varscan2
- CBLB | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV51426680; called by muse, mutect2, varscan2
- CCDC102B | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV60141797; called by muse, mutect2, varscan2
- CCDC18 | c.1643G>C p.R548T (on ENST00000343253 / NM_001306076.1; = p.R549T on NM_206886.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58141165, COSV58143478; called by muse, mutect2, varscan2
- CD207 | c.648G>A p.W216* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as rs782816989; called by muse, mutect2, varscan2
- CDH1 | c.2392C>G p.L798V | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV55732716; called by muse, mutect2, varscan2
- CDON | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.186); catalogued as COSV54997893; called by muse, mutect2, varscan2
- CELF3 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51883410; called by muse, mutect2, varscan2
- CFAP43 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV63853124; called by muse, mutect2, varscan2
- CFAP46 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.617); catalogued as COSV63951037, COSV63951118; called by muse, mutect2, varscan2
- CHD6 | c.4939C>G p.Q1647E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV64690748; called by muse, mutect2, varscan2
- CLCNKB | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65160484; called by muse, mutect2, varscan2
- COG5 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs772314269, COSV51750849; called by muse, mutect2, varscan2
- COL4A4 | c.2246C>A p.S749* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV61629456; called by muse, mutect2, varscan2
- CSMD3 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs1362181458, COSV52180244; called by muse, mutect2, varscan2
- CSMD3 | c.679T>A p.S227T | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV52180261; called by muse, mutect2, varscan2
- CYP2B6 | c.1071G>C p.Q357H | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57843722; called by muse, mutect2, varscan2
- CYP46A1 | c.441G>C p.R147= | Splice Region (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55894519; called by muse, mutect2, varscan2
- CYP4A22 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV53740091, COSV53740877; called by muse, mutect2, varscan2
- DBN1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV52789611; called by muse, varscan2
- DEK | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.116); catalogued as rs755415804, COSV55237637; called by muse, mutect2, varscan2
- DENND2A | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV52051453; called by muse, mutect2, varscan2
- DHRS7 | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53666055; called by muse, mutect2, varscan2
- DNAH2 | c.10901C>T p.S3634L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV66719457; called by muse, mutect2, varscan2
- DNMT1 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV61579345; called by muse, mutect2, varscan2
- DOCK2 | c.3598C>T p.R1200C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV56958660, COSV56967914; called by muse, mutect2, varscan2
- EPB41L3 | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as COSV59453425; called by muse, mutect2, varscan2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2
- FREM2 | c.4897G>A p.D1633N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs776357642, COSV54837677; called by muse, mutect2, varscan2
- GABPA | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV61396156, COSV61396269; called by muse, mutect2, varscan2
- GCNA | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 312/378 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101032425, COSV65466748; called by muse, varscan2
- GDF2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs137873272; called by muse, mutect2, varscan2
- GPALPP1 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV100689163, COSV62705805; called by muse, mutect2, varscan2
- GPC6 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.714); catalogued as COSV65511848; called by muse, mutect2, varscan2
- GRHL3 | c.862G>A p.D288N (on ENST00000350501 / NM_198174.3; = p.D293N on NM_021180.3) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs141594535; called by muse, mutect2, varscan2
- GSKIP | c.399G>C p.L133F | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV68451352; called by muse, mutect2, varscan2
- HELZ | c.2720G>A p.G907E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62378493; called by muse, mutect2, varscan2
- HORMAD1 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as rs150156011; called by muse, varscan2
- HPS4 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV61103456; called by muse, mutect2, varscan2
- IGF2R | c.5641G>C p.E1881Q | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.974); catalogued as COSV63629148; called by muse, mutect2, varscan2
- IL6 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.059); catalogued as COSV51732711; called by muse, mutect2
- IL6R | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs777927714, COSV59816559; called by muse, mutect2, varscan2
- JAG1 | c.2929G>C p.E977Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.677); catalogued as COSV54756807; called by muse, mutect2
- KCNIP1 | c.120G>A p.M40I (on ENST00000411494 / NM_001034837.3; = p.M29I on NM_014592.4) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV61084488; called by muse, mutect2, varscan2
- KCNJ2 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV54661744; called by muse, mutect2, varscan2
- KIAA1109 | c.4168G>A p.D1390N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs760947422, COSV52672924; called by muse, mutect2, varscan2
- KIF1A | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 15/65 reads (23%) | catalogued as COSV57494948; called by muse, mutect2, varscan2
- KIF26A | c.2062T>A p.S688T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV59466596; called by muse, mutect2
- KLHDC4 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0.009); catalogued as COSV54508110; called by muse, mutect2, varscan2
- KLHL13 | c.473C>G p.S158C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV53247544; called by muse, mutect2, varscan2
- KLK6 | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59565614; called by muse, mutect2, varscan2
- KMT2C | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100064675; called by muse, mutect2, varscan2
- KMT2D | c.6040C>T p.Q2014* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99976550; called by muse, mutect2, varscan2
- LRRC2 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 65/93 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV56126157; called by muse, mutect2, varscan2
- LRRC7 | c.2731G>A p.E911K (on ENST00000651989 / NM_001370785.2; = p.E878K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as COSV50457217; called by muse, mutect2, varscan2
- LYG2 | c.251T>A p.I84N | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60715755, COSV60716219; called by muse, mutect2, varscan2
- MED15 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); catalogued as rs1340502925; called by muse, mutect2
- MEFV | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV54822007; called by muse, mutect2, varscan2
- MFSD1 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.221); catalogued as COSV51840703, COSV51843438; called by muse, mutect2
- MICALL2 | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs762258467, COSV52515839; called by muse, mutect2, varscan2
- MOGS | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52028222; called by muse, mutect2, varscan2
- MOK | c.261G>A p.M87I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV51964967; called by muse, mutect2, varscan2
- MORC2 | c.1609G>C p.E537Q (on ENST00000397641 / NM_001303256.3; = p.E475Q on NM_014941.3) | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as COSV53198707; called by muse, mutect2, varscan2
- MPHOSPH6 | c.256-1G>T p.X86_splice | Splice Site (SNP) | VAF 37/74 reads (50%) | catalogued as COSV50736778; called by muse, mutect2, varscan2
- MPP2 | c.868G>T p.D290Y (on ENST00000461854 / NM_001278372.2; = p.D266Y on NM_005374.5) | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52235813; called by muse, mutect2, varscan2
- MRPL1 | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV59674675; called by muse, mutect2, varscan2
- MTF1 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV65989054; called by muse, mutect2, varscan2
- MYBPC1 | c.2848C>G p.L950V (on ENST00000550270 / NM_206820.2; = p.L957V on NM_002465.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV62253078; called by muse, mutect2, varscan2
- MYCBP2 | c.10966C>T p.H3656Y (on ENST00000357337; = p.H3694Y on NM_015057.5) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62015700; called by muse, mutect2, varscan2
- N4BP2 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV54701906; called by muse, mutect2, varscan2
- NF1 | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV62203291; called by muse, mutect2, varscan2
- NF1 | c.3158C>G p.S1053* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as CM151314, COSV62217802, COSV62228498; called by muse, varscan2
- NLRP2 | c.1542C>G p.F514L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs553038879, COSV54755060; called by muse, mutect2, varscan2
- NRDE2 | c.535C>G p.L179V | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62963184; called by muse, mutect2, varscan2
- NUP42 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1409364224; called by mutect2, varscan2
- OGDHL | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV65102409; called by muse, mutect2, varscan2
- PAK3 | c.1339G>A p.E447K (on ENST00000262836 / NM_001324328.2; = p.E432K on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53274301; called by muse, mutect2, varscan2
- PAN2 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV57753847; called by muse, mutect2
- PCDHB11 | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); catalogued as COSV61311583, COSV61312601; called by muse, mutect2, varscan2
- PCDHB8 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.081); catalogued as rs782252678, COSV50753521; called by muse, varscan2
- PCDHGA10 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV53947239; called by muse, mutect2, varscan2
- PIGS | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV52024453; called by muse, mutect2, varscan2
- PKP2 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50730726; called by muse, mutect2, varscan2
- PLXNC1 | c.3517G>A p.V1173M | Missense Mutation (SNP) | VAF 125/282 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs541936661, COSV51575241; called by muse, mutect2, varscan2
- PRKD3 | c.2479C>T p.L827F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52213452; called by muse, mutect2, varscan2
- PROSER3 | c.1442G>C p.*481Sext*136 | Nonstop Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV99994415; called by muse, mutect2, varscan2
- RASA3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61867302; called by muse, mutect2, varscan2
- RBM27 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs780834078, COSV54589859; called by muse, mutect2, varscan2
- RHBDL2 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV56708071; called by muse, mutect2, varscan2
- RNASE13 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV100409606, COSV58794576; called by muse, mutect2, varscan2
- RPRD2 | c.3350G>A p.R1117K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1264646010, COSV64820229; called by muse, mutect2, varscan2
- RXRG | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV63232132; called by muse, mutect2, varscan2
- SCAF8 | c.3811A>G p.T1271A | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV65791710; called by muse, mutect2, varscan2
- SERPINF1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV54616207; called by muse, mutect2, varscan2
- SMC3 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62419750; called by muse, mutect2, varscan2
- SP100 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.406); catalogued as COSV50980090, COSV51004745; called by muse, mutect2, varscan2
- SPATA22 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV52152585; called by muse, mutect2
- SPINK5 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV56253941; called by muse, mutect2, varscan2
- SPRYD3 | c.971T>A p.I324N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV56853821; called by muse, mutect2, varscan2
- SPTBN1 | c.7000G>C p.V2334L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.031); catalogued as COSV63339016; called by muse, mutect2, varscan2
- SRPK2 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57573330; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 55/116 reads (47%) | PolyPhen probably damaging (0.985); catalogued as COSV59129826; called by muse, mutect2, varscan2
- SUSD3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV64937241; called by muse, mutect2, varscan2
- SYNE1 | c.5878G>C p.E1960Q (on ENST00000367255 / NM_182961.4; = p.E1967Q on NM_033071.3) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as COSV54980797; called by muse, mutect2
- TAF7L | c.1347C>T p.L449= | Splice Region (SNP) | VAF 17/92 reads (18%) | catalogued as COSV61257065; called by muse, mutect2, varscan2
- TET1 | c.5107G>A p.E1703K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV65384767; called by muse, mutect2, varscan2
- TGFBR2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 71/89 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55449689; called by muse, mutect2, varscan2
- TRAK2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60272034; called by muse, mutect2, varscan2
- TRIM23 | c.1192C>G p.H398D | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51551442; called by muse, mutect2, varscan2
- TRIM9 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as COSV53617279; called by mutect2, varscan2
- TTN | c.73575G>C p.K24525N (on ENST00000591111; = p.K17101N on NM_003319.4) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | PolyPhen possibly damaging (0.544); catalogued as COSV60060219; called by muse, mutect2, varscan2
- TUBG1 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.262); catalogued as COSV52221181; called by muse, mutect2, varscan2
- UBE4A | c.2522A>G p.Q841R (on ENST00000252108 / NM_001204077.2; = p.Q848R on NM_004788.4) | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV52804200; called by muse, mutect2, varscan2
- ULK4 | c.2666C>T p.T889M | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs565139607, COSV100092243, COSV57208792; called by muse, mutect2, varscan2
- VEPH1 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV62876470; called by muse, mutect2, varscan2
- VIPR2 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs767254624; called by muse, mutect2, varscan2
- WDR11 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV54788414; called by muse, mutect2, varscan2
- WDR72 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1210155716, COSV64746693, COSV64750607; called by muse, mutect2, varscan2
- WDR81 | c.3393del p.V1132Wfs*15 (on ENST00000409644 / NM_001163809.2; = p.V81Wfs*15 on NM_152348.4) | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs1181232518; called by pindel, varscan2
- ZBTB24 | c.32A>G p.Q11R | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV57782058; called by muse, mutect2, varscan2
- ZFP42 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58817400; called by muse, mutect2, varscan2
- ZNF462 | c.2129C>G p.T710S | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52938236; called by muse, mutect2, varscan2
- ZNF491 | c.162G>C p.R54S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV60057460, COSV60057762; called by muse, mutect2, varscan2
- ZNF518B | c.1738C>T p.H580Y | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772363436, COSV58722615; called by muse, mutect2, varscan2
- ZNF761 | c.599C>A p.S200* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as COSV61887792; called by muse, mutect2, varscan2
- BTG3 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- GPN2 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- IGHV3-30 | c.316dup p.R106Kfs*3 | Frame Shift Ins (INS) | VAF 78/524 reads (15%) | called by mutect2, varscan2
- IGHV3-30 | c.315delinsTA p.R106Kfs*3 | Frame Shift Ins (INS) | VAF 68/664 reads (10%) | called by mutect2*, pindel, varscan2*
- TIGD3 | c.886del p.L296Cfs*92 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- TRIP12 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- WDR33 | c.2331G>T p.M777I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AK1 | c.552C>T p.S184= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV56345190; called by muse, varscan2
- ANKRD13B | c.276G>A p.R92= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV67473807; called by muse, mutect2, varscan2
- ATF7IP | c.3360C>T p.L1120= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV53770844; called by muse, mutect2, varscan2
- ATP10A | c.1782G>A p.R594= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs572968049, COSV100791356, COSV63517353; called by muse, mutect2, varscan2
- BACH2 | c.2016G>A p.Q672= | Silent (SNP) | VAF 71/97 reads (73%) | catalogued as rs1224274437, COSV57592360; called by muse, mutect2, varscan2
- CASP2 | c.51G>T p.L17= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV60082260; called by muse, mutect2, varscan2
- CELSR1 | c.6087C>T p.I2029= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs748244719, COSV53085656; called by muse, mutect2, varscan2
- CLEC16A | c.1014G>T p.L338= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1182842802, COSV68499501; called by muse, mutect2, varscan2
- CSMD2 | c.2028G>A p.K676= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV53912186; called by muse, mutect2, varscan2
- DKK3 | c.894C>T p.I298= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs369574898; called by muse, mutect2, varscan2
- FAM102A | c.48C>T p.F16= | Silent (SNP) | VAF 63/194 reads (32%) | catalogued as COSV66193881; called by muse, varscan2
- FGF8 | c.192C>G p.L64= (on ENST00000344255 / NM_033164.4; = p.L46= on NM_006119.6) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV60142842; called by muse, mutect2, varscan2
- FYN | c.1479C>T p.I493= | Silent (SNP) | VAF 100/164 reads (61%) | catalogued as COSV57614290; called by muse, mutect2, varscan2
- GGH | c.306C>G p.L102= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as rs770885990, COSV52650420; called by muse, mutect2, varscan2
- H2BC13 | c.108G>A p.E36= | Silent (SNP) | VAF 96/329 reads (29%) | catalogued as COSV62440771; called by muse, mutect2, varscan2
- H4-16 | c.270G>A p.A90= | Silent (SNP) | VAF 69/130 reads (53%) | catalogued as COSV63762090; called by muse, mutect2, varscan2
- HCFC1 | c.1461C>T p.L487= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1557116102, COSV60072159; ClinVar: likely benign; called by muse, mutect2, varscan2
- HKDC1 | c.1464G>A p.Q488= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV63577110; called by muse, mutect2, varscan2
- IGHV3-73 | c.51C>G p.V17= | Silent (SNP) | VAF 102/198 reads (52%) | called by muse, mutect2, varscan2
- KCNU1 | c.124C>T p.L42= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1168219511, COSV67755835; called by muse, mutect2, varscan2
- KIF1C | c.378C>G p.L126= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV57904488; called by muse, mutect2, varscan2
- KRTAP10-3 | c.594C>G p.L198= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59962109; called by muse, mutect2, varscan2
- M1AP | c.334C>T p.L112= | Silent (SNP) | VAF 40/145 reads (28%) | catalogued as rs1383605306, COSV51844619; called by muse, mutect2, varscan2
- MKRN1 | c.678G>A p.E226= | Silent (SNP) | VAF 53/171 reads (31%) | catalogued as COSV55436715; called by muse, mutect2, varscan2
- MSH3 | c.33C>T p.L11= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs564921007, COSV54150487, COSV54152343; called by muse, mutect2, varscan2
- MSN | c.1671G>A p.K557= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as rs763920638, COSV64304031; called by muse, mutect2, varscan2
- NELFB | c.579G>A p.V193= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs1293891236, COSV58024953; called by muse, mutect2, varscan2
- NEU4 | c.483C>T p.P161= (on ENST00000391969 / NM_001167602.3; = p.P173= on NM_080741.4) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs372998493; called by muse, mutect2, varscan2
- NPY2R | c.606C>T p.A202= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as COSV61528290; called by muse, mutect2
- NTSR2 | c.645C>T p.F215= | Silent (SNP) | VAF 9/207 reads (4%) | catalogued as rs1365475454, COSV60991069; called by muse, mutect2
- OR14J1 | c.313C>T p.L105= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as COSV101012814, COSV65845672; called by muse, mutect2, varscan2
- P2RX3 | c.915C>T p.F305= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs150261482; called by muse, mutect2, varscan2
- PCNX1 | c.2304C>T p.V768= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV53094718; called by muse, mutect2, varscan2
- PDE4DIP | c.4194G>T p.L1398= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100518517, COSV57695861; called by muse, mutect2
- RGS14 | c.720C>T p.L240= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs895344013; called by muse, mutect2, varscan2
- SLC43A3 | c.414C>T p.I138= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV61450394, COSV61451495; called by muse, mutect2, varscan2
- SLC7A3 | c.657C>A p.L219= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99979242; called by muse, mutect2
- SLC7A4 | c.1503G>A p.S501= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs761948595; called by muse, mutect2
- SNCAIP | c.1242G>A p.L414= | Silent (SNP) | VAF 39/61 reads (64%) | catalogued as COSV54410214; called by muse, mutect2, varscan2
- SNX31 | c.354T>C p.Y118= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV61263055; called by muse, mutect2, varscan2
- SORCS1 | c.3027G>A p.L1009= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs1288252945, COSV53866340; called by muse, mutect2, varscan2
- SORCS1 | c.528C>A p.A176= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV53866353; called by muse, mutect2, varscan2
- SORCS3 | c.2196G>A p.L732= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs369535493; called by muse, mutect2, varscan2
- SPACA3 | c.234C>T p.L78= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs777105777, COSV52191175; called by muse, mutect2, varscan2
- SPRED3 | c.102C>T p.V34= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV58313593; called by muse, mutect2
- THUMPD2 | c.1275T>A p.P425= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV53187582; called by muse, mutect2, varscan2
- TJP3 | c.1068C>G p.P356= | Silent (SNP) | VAF 52/168 reads (31%) | catalogued as COSV53662450; called by muse, mutect2, varscan2
- TLE1 | c.622C>T p.L208= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV64690367; called by muse, mutect2, varscan2
- TRAF3 | c.1083G>A p.V361= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as COSV61025266; called by muse, mutect2, varscan2
- TTN | c.38205C>T p.I12735= (on ENST00000591111; = p.I5311= on NM_003319.4) | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV60060276; called by muse, mutect2, varscan2
- TULP4 | c.2172G>A p.L724= | Silent (SNP) | VAF 90/125 reads (72%) | catalogued as COSV65575634; called by muse, mutect2, varscan2
- UBXN8 | c.636C>T p.Y212= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as rs770362555, COSV55664735; called by muse, mutect2, varscan2
- UMOD | c.1893C>A p.L631= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV56775677; called by muse, mutect2, varscan2
- WFS1 | c.1365G>A p.T455= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs769749907, COSV56987461, COSV56989023; called by muse, mutect2, varscan2
- ZFP57 | c.900C>T p.T300= | Silent (SNP) | VAF 117/145 reads (81%) | catalogued as COSV65306128, COSV65306551; called by muse, mutect2, varscan2
- ZNF695 | c.327G>A p.V109= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV60585930; called by muse, mutect2, varscan2
- DLG2 | c.205-65789G>C | Intron (SNP) | VAF 112/263 reads (43%) | catalogued as COSV54644220; called by muse, mutect2, varscan2
- FBXL13 | c.496-5633G>A | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- FOLH1B | n.1006G>A | RNA (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- PDXK | c.88-1547C>T | Intron (SNP) | VAF 40/110 reads (36%) | catalogued as COSV52362506; called by muse, mutect2, varscan2
- Y_RNA | chr7:75514691 C>T | 5'Flank (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
